Gene-level copy-number profile of tumor specimen TARGET-10-PATNAM-09A from TARGET case TARGET-10-PATNAM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (814 days).
Specimen TARGET-10-PATNAM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d39f1a48-e82e-5d7b-b896-80515c725810.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATNAM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate.
https://portal.gdc.cancer.gov/files/b2d0d98e-4a1d-4e24-b637-2c79235464d1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 666; copy number 1: 677; copy number 2: 58,844; copy number 3: 3; copy number 4: 28; copy number 5: 21; copy number 6: 28.

Homozygous deletions (total copy number 0; autosomes only): 146 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,311,808, 11 genes: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:142,313,184–142,779,537, 64 genes (broad region; genes not listed).
- chr9:21,802,636–22,029,594, 7 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT.
- chr14:21,941,128–22,490,553, 64 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 2–6): AC244205.1.
- chr2:88,857,161–89,143,160, 27 genes, copy number 6: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20.
- chr10:45,815,428–46,537,864, 21 genes, copy number 5 (within-gene range 2–5): FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P, ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.

Autosomal genes at a single copy (total copy number 1): 676. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
